Gene-level copy-number profile of tumor specimen ALCH-AEOF-TTP1-A from ALCHEMIST case ALCH-AEOF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,886 days).
Specimen ALCH-AEOF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b99764db-5ee8-49f0-8712-c5b0433d68ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEOF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,237 have no estimate.
https://portal.gdc.cancer.gov/files/b9fcc781-e14d-427e-84ee-36b0171e49d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 731; copy number 2: 54,076; copy number 3: 3,142; copy number 4: 410; copy number 5: 20; copy number 6: 2; copy number 8: 2; copy number 9: 2; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,952,625–7,104,482, 3 genes, copy number 5 (within-gene range 3–5): AC079804.3, MIR3683, AC092104.1.
- chr16:32,475,051–32,615,639, 2 genes, copy number 6: ABCD1P3, AC137800.1.
- chr16:32,877,469–32,888,874, 2 genes, copy number 9: SLC6A10P, AC142086.1.
- chr16:33,043,609–33,554,408, 18 genes, copy number 5–11: AC145350.2, AC145350.3, HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.4.
- chr22:18,636,445–18,653,617, 2 genes, copy number 8: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 727. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
